TCGA case TCGA-JX-A3PZ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3df6abe2-2123-4bfa-a4e4-88df5f940c04

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 25 years; Vital status: Dead; Days to death: 642 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (5)
1. Squamous cell carcinoma, keratinizing, NOS (the primary disease): ICD-O-3 morphology code: 8071/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 25.5 years (9,303 days); Year of diagnosis: 1995; Method of diagnosis: Biopsy; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; FIGO stage: Stage IB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 22; Lymphatic invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion); adjuvant Radiation Therapy, NOS, postoperative (reason: Not Done per Treating Physician's Discretion).
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Pelvis, NOS. Age at diagnosis: 26.8 years (9,794 days); Days to diagnosis: 491 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Surgery, NOS, for recurrent disease.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Brain, NOS. Age at diagnosis: 27.2 years (9,920 days); Days to diagnosis: 617 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
4. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Upper limb, NOS. Age at diagnosis: 27.2 years (9,920 days); Days to diagnosis: 617 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 1 (Squamous cell carcinoma, keratinizing, NOS), site: Thorax, NOS. Age at diagnosis: 27.2 years (9,920 days); Days to diagnosis: 617 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (11 entries)
- Day -1 (preoperative): Days to imaging: -1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day -1 (preoperative): Days to imaging: -1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day -1 (preoperative): Days to imaging: -1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day -1 (preoperative): Days to imaging: -1 day; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day -1 (preoperative): Days to imaging: -1 day; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Parametrium Involvement.
- Day 491 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvis, NOS; Days to recurrence: 491 days (1.3 years); Evidence of recurrence type: Histologic Confirmation.
- Day 538 (prior to adjuvant therapy): ECOG performance status: 0.
- Day 617 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 617 days (1.7 years).
- Day 617 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 617 days (1.7 years).
- Day 617 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 617 days (1.7 years).
- Days to follow up: 642 days (1.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Initial Diagnosis; Weight: 58 kg; Height: 175 cm; BMI: 18.9.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JX-A3PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 210 mg.
  Slide TCGA-JX-A3PZ-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-JX-A3PZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JX-A3PZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 0; Tobacco smoking history indicator: 1; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; Cause of death: Cervical Cancer.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Present; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent.
- Treatment, Radiation therapy info: Radiation treatment reason not completed: Not done per treating physician discretion.
- Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 642 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 642 days; disease-free interval: event (new tumor event after initially disease-free), 491 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 491 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JX-A3PZ-01A-11D-A21P-01): tumor purity 0.7, ploidy 3.7, whole-genome doublings 1.
